CCDI case PBBSCT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/6a3b76d6-bba8-42b8-beb8-9db9d1633f9c

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Chordoma, NOS: ICD-O-3 morphology code: 9370/3; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 10.9 years (3,970 days).

Biospecimens (3 samples)
- Sample 0DI1JM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI1UZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI1YL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
